CPTAC case C3N-01851 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d00a5d22-92b1-445b-83eb-73409012528f

Demographics
Sex at birth: male; Race: white; Year of birth: 1969; Vital status: Dead; Days to death: 363 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 47.9 years (17,508 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 363 days; Progression or recurrence: yes; Days to last follow up: 363 days.
   Pathology details: Greatest tumor dimension: 5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 363 days; Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 248 days; Karnofsky performance status: 80; ECOG performance status: 1.

Other clinical attributes
- Weight: 103 kg; Height: 184 cm; BMI: 30.42.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 66; Cigarettes per day: 40; Tobacco smoking onset year: 1983; Alcohol history: Yes; Alcohol intensity: Non-Drinker; Exposure duration years: 39.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01851-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 151 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01851-21: Section location: Left Hemisphere; Percent tumor nuclei: 65; Percent necrosis: 30.
- Sample C3N-01851-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
